MMRF case MMRF_2270 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/4764ef54-cd8b-478f-9bc0-66ceaa98e9cd

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 56.5 years (20,654 days); ISS stage: II; Days to last known disease status: 819 days (2.2 years); Days to last follow up: 819 days (2.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 99 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 110 days; Days to treatment end: 111 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 113 days; Days to treatment end: 113 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 226 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 1): M Protein 5.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 56.7 mg/dL; Immunoglobulin G 2.1 g/L; Immunoglobulin A 57.2 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 5.3 µg/mL; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 98 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.8 mmol/L; Albumin 34 g/L; Total Protein 10.7 g/dL; Glucose 7.48 mmol/L.
- Day 71 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.5 mg/dL; Immunoglobulin G 3.73 g/L; Immunoglobulin A 2.05 g/L; Immunoglobulin M 0.288 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 5.5 mmol/L.
- Day 155 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2 mg/dL; Immunoglobulin G 6.5 g/L; Immunoglobulin A 1.14 g/L; Immunoglobulin M 0.314 g/L; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 304 ×10⁹/L; Creatinine 136 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 7.2 g/dL; Glucose 4.51 mmol/L.
- Day 214 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.6 mg/dL; Immunoglobulin G 6.03 g/L; Immunoglobulin A 0.414 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 6.8 g/dL; Glucose 3.91 mmol/L.
- Day 364: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.6 mg/dL; Immunoglobulin G 4.93 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.06 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 1.5 ×10⁹/L; Absolute Neutrophil 0.6 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Albumin 40 g/L; Glucose 4.07 mmol/L.
- Day 448: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.4 mg/dL; Immunoglobulin G 5.41 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.05 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Albumin 44 g/L; Total Protein 6.3 g/dL; Glucose 4.29 mmol/L.
- Day 532: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 4.8 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.05 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Albumin 41 g/L; Total Protein 5.9 g/dL; Glucose 4.51 mmol/L.
- Day 589: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.75 mg/dL; Immunoglobulin G 5.12 g/L; Immunoglobulin A 0.47 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 8 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Albumin 40 g/L; Total Protein 5.6 g/dL; Glucose 4.29 mmol/L.
- Day 707: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.53 mg/dL; Immunoglobulin G 4.72 g/L; Immunoglobulin A 0.51 g/L; Immunoglobulin M 0.08 g/L; Hemoglobin 7.94 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Albumin 41 g/L; Total Protein 5.9 g/dL; Glucose 5.39 mmol/L.
- Day 819: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.61 mg/dL; Immunoglobulin G 5.01 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.05 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Albumin 37 g/L; Total Protein 5.5 g/dL; Glucose 5.89 mmol/L.

Other clinical attributes
- Day 0: Weight: 105 kg; Height: 175 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2270_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_2270_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
